Somatic mutation profile of tumor specimen TCGA-ER-A19W-06A (aliquot TCGA-ER-A19W-06A-41D-A23B-08) from TCGA case TCGA-ER-A19W, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 59.7 years (21,798 days).
Specimen TCGA-ER-A19W-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d80d0141-8821-4eac-9d72-903176e20217.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A19W-10A (Blood Derived Normal), aliquot TCGA-ER-A19W-10A-01D-A23B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d465e887-43f2-4f28-a1cd-03b2acb55279

The open-access MAF lists 404 somatic variants for this specimen: 246 protein-altering or splice-affecting, 148 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 216, Silent 148, Nonsense Mutation 21, Intron 6, Splice Site 4, RNA 3, Splice Region 1, 5'UTR 1, Translation Start Site 1, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDK4 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 16/90 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs11547328, CM960267, COSV56984534, COSV56985244; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CYBB | c.1223G>A p.G408E | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs151344474, CM960460, COSV66086124; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 32/188 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABCA2 | c.4138C>T p.P1380S (on ENST00000614293; = p.P1350S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1262114631, COSV55805440; called by muse, mutect2
- ABCA4 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV64675879; called by muse, mutect2, varscan2
- ABCA4 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs1199849243, COSV100933140; called by muse, mutect2, varscan2
- ACACB | c.1912C>T p.P638S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.034); catalogued as rs778629713, COSV58132822; called by muse, mutect2, varscan2
- ACOT11 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.484); catalogued as rs1278466398, COSV59351102; called by muse, mutect2
- ACTR8 | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs1177122680, COSV51638219; called by muse, mutect2
- ADAM19 | c.2453C>T p.S818F | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.656); catalogued as COSV57437442; called by muse, mutect2, varscan2
- ADAMDEC1 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.793); catalogued as COSV56477064; called by muse, mutect2
- ADGRF1 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs868151607, COSV51946345; called by muse, mutect2, varscan2
- ADGRV1 | c.11698G>A p.E3900K | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV67985801, COSV67991956; called by muse, mutect2
- ADH1B | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 43/223 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1183413755, COSV59297841; called by muse, mutect2, varscan2
- ADH1C | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 49/468 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72463625; called by muse, mutect2, varscan2
- AFF4 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as COSV54792285; called by muse, mutect2, varscan2
- ANO1 | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100304097; called by muse, mutect2, varscan2
- APOB | c.7601G>A p.R2534Q | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.037); catalogued as rs866435648, COSV51948682; called by muse, mutect2, varscan2
- ARFGEF1 | c.5207G>A p.R1736Q | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as rs1261248319, COSV99142593; called by muse, mutect2
- ARSF | c.1039G>A p.G347R | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867180334, COSV100839635, COSV63839153; called by muse, mutect2, varscan2
- ASB16 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs145226168; called by mutect2, varscan2
- ATG2B | c.3124G>A p.D1042N | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV63424986; called by muse, mutect2, varscan2
- B3GAT1 | c.371C>A p.P124Q | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.017); catalogued as COSV57000076; called by muse, mutect2, varscan2
- BLNK | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV56414349; called by muse, mutect2, varscan2
- BPTF | c.6608T>G p.I2203S | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV58844817; called by muse, mutect2, varscan2
- BRICD5 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs200895699; called by muse, mutect2, varscan2
- C1S | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV61072094; called by muse, mutect2
- C21orf62 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as rs777068813, COSV66672380; called by muse, mutect2, varscan2
- CAP2 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.977); catalogued as COSV57735936; called by muse, mutect2, varscan2
- CASR | c.2833G>A p.D945N (on ENST00000490131; = p.D1022N on NM_000388.4) | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.07); catalogued as COSV56140654; called by muse, mutect2, varscan2
- CATSPER4 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58794269; called by muse, varscan2
- CCDC105 | c.946A>G p.K316E | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.664); catalogued as COSV52965320; called by muse, mutect2, varscan2
- CCDC25 | c.220C>T p.L74F | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62959331; called by muse, mutect2, varscan2
- CCDC66 | c.830T>C p.L277S (on ENST00000394672 / NM_001353147.1; = p.L243S on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58308221; called by muse, mutect2
- CD244 | c.1007C>T p.S336F (on ENST00000368033 / NM_001166663.2; = p.S331F on NM_016382.4) | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV54436901; called by muse, mutect2, varscan2
- CDC14A | c.1345A>G p.K449E | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.165); catalogued as rs752941272, COSV60562288; called by muse, mutect2, varscan2
- CDH18 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1322473849, COSV56937420; called by muse, mutect2
- CDK7 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.416); catalogued as rs1184687649, COSV56515337; called by muse, mutect2, varscan2
- CIT | c.2533C>T p.H845Y | Missense Mutation (SNP) | VAF 61/362 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as rs762575363, COSV99949858; called by muse, mutect2, varscan2
- CMYA5 | c.9769G>A p.D3257N | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV71408902; called by muse, mutect2
- CNTN5 | c.2915C>T p.S972F | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV54347087; called by muse, mutect2, varscan2
- COBL | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV54355588; called by muse, mutect2, varscan2
- COL6A6 | c.220A>G p.K74E | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV62034606; called by muse, mutect2, varscan2
- COL6A6 | c.988C>T p.Q330* | Nonsense Mutation (SNP) | VAF 31/221 reads (14%) | catalogued as COSV62034620; called by muse, mutect2, varscan2
- COL9A1 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV57891307; called by muse, mutect2, varscan2
- CPAMD8 | c.2315G>A p.G772E (on ENST00000651564; = p.G725E on NM_015692.5) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs1483817777, COSV52238710; called by muse, mutect2, varscan2
- CPLX1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.974); catalogued as COSV58375725, COSV58377226; called by muse, mutect2, varscan2
- CRHBP | c.902T>G p.L301R | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57189689; called by muse, mutect2, varscan2
- CSF2RB | c.2416A>G p.T806A | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53260379; called by muse, mutect2
- CSTA | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs770962641, COSV52612781; called by muse, mutect2, varscan2
- CUBN | c.2797G>A p.G933R | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs922057596, COSV64724692; called by muse, mutect2, varscan2
- CX3CR1 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64194994; called by muse, mutect2, varscan2
- CYB5R3 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV61546377; called by muse, mutect2
- DBF4B | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs763351525, COSV59262946; called by muse, mutect2
- DCAF6 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV56583801; called by muse, mutect2, varscan2
- DEFB116 | c.260C>A p.S87Y | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as COSV68722371; called by muse, mutect2, varscan2
- DENND3 | c.2893G>A p.D965N | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52805649; called by muse, mutect2, varscan2
- DHTKD1 | c.901A>G p.T301A | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.669); catalogued as COSV53806229; called by muse, mutect2, varscan2
- DNAH14 | c.931C>A p.P311T (on ENST00000445597; = p.P184T on NM_144989.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV64782313; called by muse, mutect2, varscan2
- DNAH5 | c.4489G>A p.E1497K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.96); PolyPhen benign (0.005); catalogued as COSV54243119; called by muse, mutect2, varscan2
- DNAH7 | c.3832C>T p.H1278Y | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV56771861; called by muse, mutect2
- DSP | c.6079G>A p.E2027K | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs762538310, COSV65792113; called by muse, mutect2, varscan2
- EDRF1 | c.1897C>T p.P633S (on ENST00000356792 / NM_001202438.2; = p.P599S on NM_015608.2) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV61765813; called by muse, mutect2, varscan2
- EFCAB6 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs906091427, COSV53070476; called by muse, mutect2, varscan2
- ELN | c.1357+1G>A p.X453_splice | Splice Site (SNP) | VAF 14/81 reads (17%) | catalogued as CD004171, COSV52714338; called by muse, mutect2, varscan2
- ENC1 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.141); catalogued as COSV56630847; called by muse, mutect2, varscan2
- ERICH3 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV58615509; called by muse, mutect2, varscan2
- EXD1 | c.1001T>A p.V334E | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.87); PolyPhen benign (0.026); catalogued as COSV59256201; called by muse, mutect2, varscan2
- FAM111A | c.700T>A p.F234I | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV64655759; called by muse, mutect2, varscan2
- FAM83F | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1008750037, COSV61001055; called by muse, mutect2, varscan2
- FAT4 | c.5566C>T p.P1856S | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV58703329; called by muse, mutect2, varscan2
- FCRL2 | c.955C>T p.L319F | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.951); catalogued as COSV63834871; called by muse, mutect2, varscan2
- FGFR4 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52801991; called by muse, mutect2
- FGFRL1 | c.1178C>T p.T393I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV53258972; called by muse, mutect2, varscan2
- FKBP5 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs374759584; called by muse, mutect2, varscan2
- FLCN | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as CD051306, COSV53262505; called by muse, mutect2, varscan2
- FNDC1 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779471491, COSV51940700; called by muse, mutect2, varscan2
- FOLR1 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.927); catalogued as rs566120497, COSV56616972, COSV56617000; called by muse, mutect2, varscan2
- FREM1 | c.2187G>A p.M729I | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV66524150, COSV66532000; called by muse, mutect2, varscan2
- FRMPD4 | c.2297A>G p.N766S | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV66221562; called by muse, mutect2, varscan2
- FSHB | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.554); catalogued as COSV54221444; called by muse, mutect2, varscan2
- FUT11 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs750140528, COSV100226882; called by muse, mutect2, varscan2
- GALNS | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.174); catalogued as COSV51939916; called by muse, mutect2, varscan2
- GDAP1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99619612; called by muse, mutect2, varscan2
- GKN1 | c.74A>T p.N25I | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.184); catalogued as COSV65006778; called by muse, mutect2
- GLRA1 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV51008024; called by muse, mutect2, varscan2
- GPR50 | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 83/351 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.293); catalogued as COSV54442071; called by muse, mutect2, varscan2
- GRIK2 | c.1679C>T p.S560F | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59716245, COSV59768179; called by muse, mutect2, varscan2
- HADHA | c.200A>T p.E67V | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.493); catalogued as COSV101024291, COSV66108451; called by muse, mutect2, varscan2
- HCN1 | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57532358; called by muse, mutect2, varscan2
- HSPG2 | c.7222C>T p.R2408* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as rs971544326, COSV65975963; called by muse, mutect2, varscan2
- HYLS1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV54992139; called by muse, mutect2, varscan2
- IGHV3-43 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); catalogued as rs182650845; called by muse, mutect2, varscan2
- IGLL5 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV66537945; called by muse, mutect2, varscan2
- IL36B | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.162); catalogued as rs755811144, COSV52084410; called by muse, mutect2, varscan2
- INCA1 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV57906365; called by muse, mutect2, varscan2
- INPP5F | c.759T>G p.D253E | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.259); catalogued as COSV62823244; called by muse, mutect2, varscan2
- IREB2 | c.1393C>T p.Q465* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV51925967; called by muse, mutect2, varscan2
- ITGA10 | c.2324C>T p.S775L | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.636); catalogued as rs1553746051, COSV65198784; called by muse, mutect2, varscan2
- ITLN1 | c.482G>A p.W161* | Nonsense Mutation (SNP) | VAF 45/124 reads (36%) | catalogued as COSV58276487; called by muse, mutect2, varscan2
- ITPR3 | c.4535C>T p.P1512L | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.155); catalogued as rs771517190, COSV65410487; called by muse, mutect2, varscan2
- KALRN | c.2414C>T p.T805I | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764993094, COSV53776857; called by muse, mutect2, varscan2
- KIAA1522 | c.1550G>A p.R517Q (on ENST00000373480 / NM_001198972.2; = p.R576Q on NM_020888.3) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746211710, COSV53863448; called by muse, mutect2, varscan2
- KIF21B | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV59764260; called by muse, mutect2, varscan2
- KLHDC7A | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1553122963, COSV68769075; called by muse, mutect2, varscan2
- KLKB1 | c.1192T>G p.S398A | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.021); catalogued as COSV52998499; called by muse, mutect2, varscan2
- KNDC1 | c.1196C>T p.S399L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV58838844; called by muse, mutect2, varscan2
- KRT36 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs142512887; called by muse, mutect2, varscan2
- KRTAP12-1 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781864579, COSV59975768; called by muse, varscan2
- LAMA3 | c.1141C>T p.Q381* | Nonsense Mutation (SNP) | VAF 5/96 reads (5%) | catalogued as COSV58077187; called by muse, mutect2
- LAMA5 | c.10762G>A p.G3588R | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as COSV53369562; called by muse, mutect2
- LANCL3 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV66129818; called by muse, mutect2
- LCMT2 | c.1859C>T p.T620I | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs1210428419, COSV59791490; called by muse, mutect2, varscan2
- LOXL2 | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV66693083; called by muse, mutect2, varscan2
- LRP1B | c.2044G>A p.D682N | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.072); catalogued as COSV67203248; called by muse, mutect2, varscan2
- LY75 | c.324G>A p.W108* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as COSV55107569; called by muse, mutect2, varscan2
- MAGEA11 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.082); catalogued as rs1557362563, COSV60758128; called by muse, mutect2, varscan2
- MAML1 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV52988183; called by muse, mutect2, varscan2
- MAP2K5 | c.1139C>T p.S380L (on ENST00000178640 / NM_145160.3; = p.S370L on NM_002757.4) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs769775880, COSV51612407; called by muse, mutect2, varscan2
- MAPK10 | c.833C>T p.S278F (on ENST00000359221 / NM_001351625.2; = p.S316F on NM_002753.5) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV60391634; called by muse, mutect2, varscan2
- MARCHF4 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56107783; called by muse, mutect2
- MARCO | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59057512; called by muse, mutect2
- MCOLN2 | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs761807547, COSV52299020; called by muse, mutect2, varscan2
- MDN1 | c.7955C>T p.S2652F | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV65528501; called by muse, mutect2, varscan2
- ME1 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.932); catalogued as rs1262440067, COSV63839097; called by muse, mutect2, varscan2
- MGAM | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.398); catalogued as COSV72073548; called by muse, mutect2, varscan2
- MLIP | c.218G>A p.R73K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0.033); catalogued as rs1375036046, COSV51435389; called by muse, mutect2
- MMP10 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54247422; called by muse, mutect2
- MYH4 | c.5542G>A p.E1848K | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55124482; called by muse, varscan2
- MYH7 | c.3264T>G p.N1088K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as COSV62522818; called by muse, mutect2, varscan2
- MYLK | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.335); catalogued as COSV100659171; called by muse, mutect2, varscan2
- MYO9B | c.4512G>C p.Q1504H | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as COSV68277797, COSV68282122; called by muse, mutect2, varscan2
- MYT1L | c.1909G>T p.E637* | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as COSV67721392, COSV67728299, COSV67729946; called by muse, mutect2, varscan2
- NBEAL2 | c.6781C>T p.Q2261* | Nonsense Mutation (SNP) | VAF 11/106 reads (10%) | catalogued as COSV52762068; called by muse, mutect2, varscan2
- NCAM2 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53097556; called by muse, mutect2, varscan2
- NCF1 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56877159; called by muse, mutect2, varscan2
- NDNF | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.966); catalogued as rs1297231652, COSV65634520; called by muse, mutect2, varscan2
- NLRC3 | c.2419G>A p.G807S | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV57092224; called by muse, mutect2
- NLRP12 | c.2462C>T p.S821F | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60753269; called by muse, mutect2, varscan2
- NUBP1 | c.821-2A>T p.X274_splice | Splice Site (SNP) | VAF 28/120 reads (23%) | catalogued as COSV51595285; called by muse, mutect2, varscan2
- NUP214 | c.2165C>A p.A722D | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV100845301; called by muse, mutect2, varscan2
- NUP93 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV57433246; called by muse, mutect2, varscan2
- OBSCN | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as rs775776629, COSV99479384; called by muse, mutect2, varscan2
- OR4K2 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 32/398 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as rs780176630, COSV53849494, COSV53851787; called by muse, mutect2
- OR4K5 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as rs1489261314, COSV60002231; called by muse, mutect2, varscan2
- OR4S2 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56746257; called by muse, mutect2, varscan2
- OR51G2 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs867001321, COSV58992760; called by muse, mutect2, varscan2
- OR52H1 | c.458G>A p.R153Q (on ENST00000322653; = p.R159Q on NM_001005289.1) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as rs571302036, COSV59504840; called by muse, mutect2, varscan2
- OR5L1 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1189469041, COSV61735125; called by muse, mutect2, varscan2
- PAPPA2 | c.1229G>A p.G410E | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62773226, COSV62784722; called by muse, mutect2, varscan2
- PASK | c.2338G>A p.D780N | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV52147978, COSV52158764; called by muse, mutect2, varscan2
- PCARE | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1253679295, COSV59053048; called by muse, mutect2, varscan2
- PCSK5 | c.2300G>T p.C767F | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65094856; called by muse, mutect2, varscan2
- PHKB | c.3106C>T p.Q1036* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV54531509; called by muse, mutect2, varscan2
- PHLPP1 | c.4936C>T p.R1646* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV53024986; called by mutect2, varscan2
- PIK3R6 | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.037); catalogued as rs750347394, COSV61005190; called by muse, mutect2, varscan2
- PIKFYVE | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV52242068; called by muse, mutect2, varscan2
- PIP5K1B | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as COSV55255937; called by muse, mutect2, varscan2
- PLA2G4C | c.334C>A p.Q112K | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT tolerated (0.99); PolyPhen benign (0.013); catalogued as COSV62787411; called by muse, mutect2, varscan2
- PLCXD3 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as rs756989510, COSV60615998; called by muse, mutect2, varscan2
- PLEKHA4 | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99612652; called by muse, mutect2, varscan2
- PLEKHA4 | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV99612654; called by muse, mutect2, varscan2
- PLEKHA7 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs770560768, COSV63049947; called by muse, mutect2, varscan2
- PNPLA3 | c.802G>A p.G268R | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.13); catalogued as rs1196129570, COSV53380156; called by muse, mutect2, varscan2
- POLD3 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55245211; called by muse, varscan2
- POM121 | c.1751C>T p.S584F (on ENST00000434423; = p.S319F on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs200541969, COSV99988312; called by mutect2, varscan2
- PPIL2 | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV58608603; called by muse, mutect2
- PPP2R2B | c.597G>A p.W199* (on ENST00000394409; = p.W265* on NM_181674.2) | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV60775641; called by muse, mutect2, varscan2
- PPP6R2 | c.619-1G>A p.X207_splice | Splice Site (SNP) | VAF 13/180 reads (7%) | catalogued as COSV53297357; called by muse, mutect2
- PRDM1 | c.1148C>T p.T383M | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.346); catalogued as rs548489075, COSV64846037; ClinVar: not provided; called by muse, mutect2
- PRDM11 | c.964G>A p.D322N (on ENST00000530656 / NM_001359633.1; = p.D288N on NM_001256695.1) | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); catalogued as COSV55442946; called by muse, mutect2, varscan2
- PRSS54 | c.506G>A p.W169* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as COSV54687378; called by muse, mutect2, varscan2
- PRTG | c.2804A>G p.K935R | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1481898038, COSV66840103; called by muse, mutect2, varscan2
- PTK6 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs765004968, COSV53918122, COSV99420278; called by muse, mutect2, varscan2
- PTPRF | c.2186G>A p.W729* | Nonsense Mutation (SNP) | VAF 26/119 reads (22%) | catalogued as COSV63448046; called by muse, mutect2, varscan2
- RAB4A | c.291C>T p.S97= | Splice Region (SNP) | VAF 33/108 reads (31%) | catalogued as rs1281220421, COSV64207894; called by muse, mutect2, varscan2
- RANBP17 | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs533115068, COSV66645560; called by muse, mutect2, varscan2
- RARA | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as COSV54195941; called by muse, mutect2, varscan2
- RASGRP1 | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs867704540, COSV60367162; called by muse, mutect2
- RASSF2 | c.933G>A p.M311I | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV65082975; called by muse, mutect2, varscan2
- RCBTB2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/144 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.38); catalogued as COSV100749594; called by muse, mutect2, varscan2
- RGL1 | c.1802C>T p.S601F (on ENST00000360851 / NM_001297672.2; = p.S636F on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV58980409; called by muse, mutect2, varscan2
- RIPOR3 | c.1514G>A p.R505K | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV50399741; called by muse, mutect2
- ROBO4 | c.2917G>A p.G973R | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100127749, COSV60625639; called by muse, mutect2, varscan2
- RORB | c.1028C>T p.A343V (on ENST00000396204 / NM_001365023.1; = p.A332V on NM_006914.4) | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV100974362; called by muse, mutect2, varscan2
- SAMD3 | c.1474G>C p.E492Q | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.169); catalogued as COSV62388371; called by muse, mutect2, varscan2
- SDHA | c.465T>G p.N155K | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.807); catalogued as COSV53772544; called by muse, mutect2, varscan2
- SENP6 | c.1670C>T p.P557L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV59193586; called by muse, mutect2, varscan2
- SEZ6 | c.2274G>A p.W758* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV57984055; called by muse, mutect2, varscan2
- SHKBP1 | c.1294C>T p.P432S | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV52542684; called by muse, mutect2, varscan2
- SLC4A7 | c.3014T>C p.I1005T | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55401610; called by muse, mutect2, varscan2
- SLC4A8 | c.2318A>T p.N773I | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.367); catalogued as COSV60657214; called by muse, mutect2, varscan2
- SLC9A4 | c.1403G>A p.G468E | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1400709902, COSV54829060; called by muse, mutect2, varscan2
- SLCO2A1 | c.1924C>T p.L642F | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV60488455; called by muse, mutect2, varscan2
- SPDYA | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV60257560; called by muse, mutect2, varscan2
- SPRR2G | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 42/125 reads (34%) | PolyPhen benign (0.439); catalogued as rs1311273262, COSV64203340; called by muse, mutect2, varscan2
- SRSF4 | c.366T>A p.D122E | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV65695522; called by muse, mutect2, varscan2
- STK24 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV64823058; called by muse, mutect2
- SYNE1 | c.26210G>A p.G8737D (on ENST00000367255 / NM_182961.4; = p.G8689D on NM_033071.3) | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV54935271, COSV99578787; called by muse, mutect2, varscan2
- SYNGAP1 | c.1819C>T p.L607F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53384838; called by muse, mutect2
- SYT8 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as rs758980969, COSV53290784; called by muse, mutect2, varscan2
- SZT2 | c.2173C>T p.P725S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.255); catalogued as COSV100987366; called by muse, mutect2, varscan2
- TACC3 | c.1409A>C p.E470A | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV57607220; called by muse, mutect2, varscan2
- TAS2R9 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); catalogued as COSV53690338; called by muse, mutect2, varscan2
- TCERG1L | c.383C>G p.P128R | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs772795939, COSV64055623; called by muse, mutect2, varscan2
- THOC5 | c.1020G>C p.M340I | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV63800594; called by muse, mutect2
- THOC5 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as COSV63800600; called by muse, mutect2, varscan2
- THUMPD2 | c.335G>A p.W112* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV53188811; called by muse, mutect2
- TIPARP | c.1811G>A p.R604K | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); catalogued as COSV55815459; called by muse, mutect2, varscan2
- TLK2 | c.2156G>A p.R719Q (on ENST00000326270 / NM_001284333.2; = p.R697Q on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs768140903, COSV58304751; called by muse, mutect2, varscan2
- TM9SF3 | c.335T>C p.L112S | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV64458401; called by muse, mutect2, varscan2
- TMEM26 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV53263914; called by muse, mutect2, varscan2
- TMEM43 | c.11A>T p.N4I | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.062); catalogued as COSV55500246; called by muse, mutect2, varscan2
- TNIK | c.3296T>A p.V1099D | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52692684; called by muse, mutect2
- TNN | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV53433512; called by muse, mutect2, varscan2
- TOPBP1 | c.1889C>T p.S630L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764317613, COSV53435727, COSV53440497; called by muse, mutect2, varscan2
- TPH1 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51459893; called by muse, varscan2
- TRIM55 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV52549797; called by muse, mutect2, varscan2
- TRIML2 | c.909G>C p.R303S | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as COSV58718884; called by muse, mutect2
- TRPC5 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 53/186 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53287023; called by muse, mutect2, varscan2
- TSGA10IP | c.1277G>A p.G426E | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.119); catalogued as COSV73245214; called by muse, mutect2, varscan2
- TSPAN9 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs781252017, COSV50722842; called by muse, mutect2, varscan2
- TUBGCP2 | c.232C>G p.L78V | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.695); catalogued as COSV53308085; called by muse, mutect2, varscan2
- TVP23C | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.913); catalogued as rs747886729, COSV56672782; called by muse, mutect2, varscan2
- TXNDC2 | c.1124C>T p.P375L (on ENST00000306084 / NM_001098529.2; = p.P308L on NM_032243.6) | Missense Mutation (SNP) | VAF 73/231 reads (32%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.979); catalogued as COSV60155200; called by muse, mutect2, varscan2
- UNC13D | c.961A>T p.T321S | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV52886782; called by muse, mutect2, varscan2
- USP19 | c.1595C>G p.A532G | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV60047955; called by muse, mutect2, varscan2
- VIRMA | c.1064A>G p.Y355C | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.929); catalogued as COSV52589754; called by muse, mutect2, varscan2
- WNK2 | c.4795C>T p.Q1599* (on ENST00000297954 / NM_001282394.1; = p.Q1562* on NM_006648.3) | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99942820; called by muse, mutect2, varscan2
- ZBED9 | c.2699C>T p.S900L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.966); catalogued as rs1241975317, COSV71729275; called by muse, mutect2
- ZC3H12C | c.2045A>G p.D682G | Missense Mutation (SNP) | VAF 63/264 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as COSV53711951; called by muse, mutect2, varscan2
- ZMYND15 | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.017); catalogued as rs1327793836, COSV52639506, COSV99350810; called by muse, mutect2, varscan2
- ZMYND15 | c.1326C>G p.D442E | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.031); catalogued as rs199761207, COSV52644360; called by muse, mutect2, varscan2
- ZNF257 | c.467A>G p.K156R | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV71306758, COSV71311179; called by muse, mutect2, varscan2
- ZNF28 | c.1804A>G p.T602A | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV60424923; called by muse, mutect2, varscan2
- ZNF287 | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 13/73 reads (18%) | catalogued as COSV67688998; called by muse, mutect2, varscan2
- ZNF490 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.747); catalogued as COSV61008898; called by muse, mutect2, varscan2
- ZNF511 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV62920239; called by muse, mutect2, varscan2
- ZNF638 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as COSV52494679; called by muse, mutect2, varscan2
- ZNF835 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 58/315 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV73379389; called by muse, mutect2, varscan2
- ZNFX1 | c.899C>T p.T300I | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV65578367; called by muse, mutect2, varscan2
- ABCA5 | c.4094_4096del p.E1365_T1366delinsA | In Frame Del (DEL) | VAF 8/57 reads (14%) | called by mutect2, pindel, varscan2
- CDC42BPB | c.1275del p.D427Mfs*31 | Frame Shift Del (DEL) | VAF 22/125 reads (18%) | called by mutect2, pindel, varscan2
- FANCB | c.944_951+1del p.X315_splice | Splice Site (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel
- FRG2C | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 24/381 reads (6%) | called by muse, mutect2
- RNMT | c.1015_1016insTA p.E339Vfs*6 | Frame Shift Ins (INS) | VAF 22/93 reads (24%) | called by mutect2, pindel, varscan2
- ABCA2 | c.6762C>T p.F2254= (on ENST00000614293; = p.F2224= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as rs1469349981, COSV55805431; called by muse, mutect2, varscan2
- ABCC1 | c.1767C>T p.F589= | Silent (SNP) | VAF 31/194 reads (16%) | catalogued as COSV60692210; called by muse, mutect2, varscan2
- ACSBG2 | c.501C>T p.I167= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV53125929; called by muse, mutect2, varscan2
- ACSM4 | c.1395C>T p.F465= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV68069050; called by muse, varscan2
- ADSS1 | c.1182G>A p.E394= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV58272286, COSV58275683; called by muse, mutect2, varscan2
- ALDH1L2 | c.1326A>C p.P442= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV51559080; called by muse, mutect2, varscan2
- ANK3 | c.423C>T p.F141= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV55076862; called by muse, mutect2, varscan2
- ANKRD1 | c.171G>A p.E57= | Silent (SNP) | VAF 36/136 reads (26%) | catalogued as COSV63311167; called by muse, mutect2, varscan2
- ANO1 | c.216G>A p.R72= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100304098; called by muse, mutect2, varscan2
- ARFGEF1 | c.5208G>A p.R1736= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV99142590; called by muse, mutect2
- ARHGAP24 | c.2157G>A p.Q719= (on ENST00000395184 / NM_001025616.3; = p.Q626= on NM_031305.3) | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV51992722; called by muse, mutect2, varscan2
- ATP5MC2 | c.297C>T p.I99= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV58602093; called by muse, mutect2, varscan2
- ATP6V0D2 | c.963G>A p.K321= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV53417113; called by muse, mutect2, varscan2
- ATR | c.1312C>T p.L438= | Silent (SNP) | VAF 19/146 reads (13%) | catalogued as COSV63390710, COSV63395250; called by muse, mutect2, varscan2
- BPIFB4 | c.1704G>A p.V568= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV64952094; called by muse, mutect2, varscan2
- BRD3 | c.525C>T p.S175= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs749422524, COSV100325146; called by muse, mutect2
- C1orf159 | c.597G>A p.P199= (on ENST00000379339 / NM_001330306.2; = p.P163= on NM_017891.5) | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs750125410, COSV53882985; called by muse, mutect2, varscan2
- C3orf56 | c.327C>T p.S109= | Silent (SNP) | VAF 42/260 reads (16%) | catalogued as COSV67756463; called by muse, varscan2
- C7 | c.2442G>A p.T814= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs374829582; called by muse, mutect2, varscan2
- CAPZA3 | c.339G>A p.E113= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV56856788; called by muse, mutect2, varscan2
- CARD6 | c.1032C>A p.I344= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV54568491, COSV54568799; called by muse, mutect2
- CCDC66 | c.828T>C p.A276= (on ENST00000394672 / NM_001353147.1; = p.A242= on NM_001012506.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV58308195; called by muse, mutect2
- CCL4L2 | c.123G>A p.R41= | Silent (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- CCR8 | c.438G>A p.T146= | Silent (SNP) | VAF 45/249 reads (18%) | catalogued as rs756158083, COSV58337806; called by muse, mutect2, varscan2
- CDK12 | c.3918C>T p.S1306= (on ENST00000447079 / NM_016507.4; = p.S1297= on NM_015083.3) | Silent (SNP) | VAF 18/252 reads (7%) | catalogued as COSV101420238, COSV70999503; called by muse, mutect2
- CEP128 | c.1122C>T p.F374= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as rs763788480, COSV53677575, COSV99382899; called by muse, mutect2, varscan2
- CHODL | c.250T>C p.L84= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as rs377519818; called by muse, mutect2, varscan2
- CIT | c.2532C>T p.D844= | Silent (SNP) | VAF 59/359 reads (16%) | catalogued as COSV99949860; called by muse, mutect2, varscan2
- CNGA2 | c.321C>T p.T107= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV61705857; called by muse, mutect2, varscan2
- COL11A1 | c.4632G>A p.Q1544= | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as rs764642153, COSV62193890; called by muse, mutect2, varscan2
- CPNE1 | c.672C>T p.I224= (on ENST00000352393; = p.I229= on NM_003915.5) | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs756128504, COSV58294255; called by muse, mutect2, varscan2
- CPT1B | c.879C>T p.I293= | Silent (SNP) | VAF 16/204 reads (8%) | catalogued as COSV56416259; called by muse, mutect2
- CYP19A1 | c.609C>T p.F203= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV53061845; called by muse, mutect2, varscan2
- CYP4A11 | c.909G>A p.G303= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs1262592132, COSV60225176; called by muse, mutect2, varscan2
- DCT | c.1513C>T p.L505= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV100986231, COSV65468945; called by muse, mutect2
- DCT | c.1512C>T p.P504= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV100986232; called by muse, mutect2
- DNAH17 | c.6036G>A p.S2012= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs754391550, COSV67754825; called by muse, mutect2, varscan2
- DNAH5 | c.4782C>T p.S1594= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as rs758663096, COSV54246406, COSV54256389; called by muse, mutect2, varscan2
- DNMT1 | c.1941C>T p.A647= | Silent (SNP) | VAF 33/179 reads (18%) | catalogued as COSV61582601; called by muse, mutect2, varscan2
- DOK1 | c.1065C>T p.D355= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV51211969; called by muse, mutect2, varscan2
- EDIL3 | c.1092G>A p.V364= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV56916595; called by muse, mutect2, varscan2
- F8 | c.1254C>T p.V418= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs1557282010, COSV64277633; called by muse, mutect2
- FABP9 | c.93G>A p.R31= | Silent (SNP) | VAF 21/124 reads (17%) | catalogued as rs750305581, COSV66911762; called by muse, mutect2, varscan2
- FAF1 | c.1668C>T p.S556= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs759049557, COSV65641096, COSV65642998; called by muse, mutect2, varscan2
- FAM189B | c.951C>T p.A317= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV56947033; called by muse, mutect2, varscan2
- FAM83B | c.1377G>A p.R459= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV60921971, COSV60925896; called by muse, mutect2, varscan2
- FCRL1 | c.844C>T p.L282= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV100839804; called by muse, mutect2, varscan2
- FCRL1 | c.843C>T p.G281= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as COSV100839805; called by muse, mutect2, varscan2
- FOXN1 | c.1500C>T p.S500= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs914906056, COSV56883708; called by muse, varscan2
- GAS2L2 | c.309C>T p.A103= | Silent (SNP) | VAF 16/116 reads (14%) | called by muse, mutect2, varscan2
- GDAP1 | c.48G>A p.A16= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV55186712; called by muse, mutect2, varscan2
- GFUS | c.303C>T p.A101= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as rs1226996755, COSV71254356; called by muse, mutect2, varscan2
- HECTD1 | c.654C>T p.T218= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs774230870, COSV67948734; called by muse, mutect2, varscan2
- IFT122 | c.3327C>T p.S1109= (on ENST00000348417 / NM_052989.3; = p.S1050= on NM_018262.4) | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as COSV56207011; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.114G>A p.R38= | Silent (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- IGLL5 | c.375G>A p.E125= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs1245005681, COSV101138835; called by muse, mutect2, varscan2
- ITGA11 | c.396C>T p.S132= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV59881108; called by muse, mutect2, varscan2
- ITPR3 | c.3210G>A p.L1070= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV65413782; called by muse, mutect2
- KALRN | c.1182C>T p.T394= | Silent (SNP) | VAF 27/119 reads (23%) | catalogued as COSV53776845; called by muse, mutect2, varscan2
- KCNB2 | c.1392G>A p.L464= | Silent (SNP) | VAF 25/170 reads (15%) | catalogued as COSV73052412; called by muse, mutect2, varscan2
- KCNJ4 | c.570C>T p.H190= | Silent (SNP) | VAF 49/105 reads (47%) | catalogued as rs540270406, COSV57858391; called by muse, mutect2, varscan2
- KCNQ1 | c.993C>T p.C331= | Silent (SNP) | VAF 33/149 reads (22%) | catalogued as CM141789, COSV50125180; called by muse, mutect2, varscan2
- KIAA1549 | c.228C>T p.S76= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as rs769408242, COSV54324966; called by muse, mutect2, varscan2
- KLHL35 | c.1287G>A p.E429= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs765127531, COSV66219652; called by mutect2, varscan2
- KMT2C | c.13614C>T p.I4538= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as rs752963593, COSV51488370; called by muse, mutect2, varscan2
- KMT5B | c.435G>A p.K145= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV58569116; called by muse, mutect2
- KRT36 | c.1266C>T p.V422= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs149830161; called by muse, mutect2, varscan2
- KRTAP12-3 | c.114G>A p.V38= | Silent (SNP) | VAF 47/229 reads (21%) | catalogued as COSV59975759; called by muse, mutect2, varscan2
- LILRB4 | c.573G>A p.G191= | Silent (SNP) | VAF 21/129 reads (16%) | catalogued as rs374286374, COSV104373865, COSV104373867, COSV54408035; called by muse, mutect2, varscan2
- LRCH4 | c.549C>T p.S183= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV53828848; called by muse, mutect2, varscan2
- LRIF1 | c.2199A>T p.P733= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as COSV63898260; called by muse, mutect2
- LRP2 | c.11970C>T p.S3990= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV55569212; called by muse, mutect2, varscan2
- LYVE1 | c.342G>A p.L114= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs561459826, COSV56283402; called by muse, mutect2, varscan2
- MAP7D1 | c.544C>T p.L182= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs1451003132, COSV60218100; called by mutect2, varscan2
- MVD | c.270C>G p.A90= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV56331567; called by muse, mutect2, varscan2
- MYLK | c.5292C>T p.I1764= | Silent (SNP) | VAF 48/278 reads (17%) | catalogued as COSV60619517; called by muse, mutect2, varscan2
- MYLK | c.84C>T p.P28= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV100659170; called by muse, mutect2, varscan2
- MYLK3 | c.420C>T p.F140= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV67366186; called by muse, mutect2, varscan2
- NBN | c.1932G>A p.Q644= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as rs754783870, COSV55376022; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEB | c.11280C>T p.I3760= | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as COSV51450608; called by muse, mutect2, varscan2
- NOC3L | c.1278C>T p.C426= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV64930478; called by muse, mutect2, varscan2
- NPAP1 | c.984G>A p.R328= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV100276366, COSV61505370; called by muse, mutect2, varscan2
- NRXN1 | c.2311C>T p.L771= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV58484161; called by muse, mutect2, varscan2
- NUGGC | c.1836G>A p.E612= | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as COSV58438161; called by muse, mutect2, varscan2
- NUP214 | c.2166C>G p.A722= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as COSV100845302; called by muse, mutect2, varscan2
- OBSCN | c.147G>A p.P49= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99479383; called by muse, mutect2, varscan2
- OR10H1 | c.846C>T p.L282= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV58472679; called by muse, mutect2, varscan2
- OR1L3 | c.729C>T p.S243= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV59170440; called by muse, mutect2, varscan2
- OR4C16 | c.486G>A p.L162= | Silent (SNP) | VAF 28/149 reads (19%) | catalogued as rs1382002295, COSV58943776; called by muse, mutect2, varscan2
- OR4C46 | c.102C>T p.I34= | Silent (SNP) | VAF 32/177 reads (18%) | catalogued as rs768611352, COSV60220873; called by muse, mutect2, varscan2
- OR4L1 | c.834C>T p.I278= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV100235879; called by muse, mutect2
- PADI4 | c.1890C>T p.I630= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV64923123; called by muse, mutect2, varscan2
- PAG1 | c.438C>T p.L146= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs1044053583, COSV55061119; called by muse, mutect2, varscan2
- PCDHB12 | c.2124C>T p.F708= | Silent (SNP) | VAF 76/347 reads (22%) | catalogued as COSV53400067; called by muse, mutect2, varscan2
- PCDHB7 | c.15G>A p.V5= | Silent (SNP) | VAF 7/90 reads (8%) | catalogued as COSV50805113; called by muse, mutect2
- PCDHGC4 | c.426T>C p.I142= | Silent (SNP) | VAF 15/130 reads (12%) | catalogued as COSV52764476; called by muse, mutect2, varscan2
- PCNX2 | c.4827G>A p.R1609= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as COSV50859946; called by muse, mutect2, varscan2
- PCSK9 | c.771G>A p.G257= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV56164210; called by muse, mutect2
- PIK3CA | c.705C>T p.S235= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV55976362, COSV99843414; called by muse, mutect2, varscan2
- PKD1 | c.8424C>T p.I2808= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as COSV51923574; called by muse, mutect2, varscan2
- PKHD1L1 | c.2607T>C p.N869= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as rs766206209, COSV65737034; called by muse, mutect2
- PKN2 | c.966C>T p.S322= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs757331391, COSV60134647; called by muse, mutect2, varscan2
- POF1B | c.216G>A p.R72= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV53139070; called by muse, mutect2, varscan2
- POM121 | c.3723C>T p.A1241= (on ENST00000434423; = p.A976= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as COSV57522623; called by muse, mutect2, varscan2
- PRAMEF1 | c.1137C>T p.L379= | Silent (SNP) | VAF 25/206 reads (12%) | called by muse, mutect2, varscan2
- PRAMEF4 | c.642G>A p.V214= | Silent (SNP) | VAF 23/233 reads (10%) | catalogued as rs756668608, COSV99339629; called by muse, mutect2, varscan2
- PREX1 | c.3591G>A p.E1197= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs200938863, COSV64255744; called by muse, mutect2
- PRL | c.648C>T p.L216= | Silent (SNP) | VAF 31/152 reads (20%) | catalogued as COSV60593399; called by muse, mutect2, varscan2
- RBPMS2 | c.387C>T p.A129= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as rs751394399, COSV55604834; called by muse, mutect2, varscan2
- ROBO1 | c.126G>A p.T42= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV71969118; called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.429C>T p.P143= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs1418813369, COSV100271687, COSV59088272; called by muse, mutect2, varscan2
- RUVBL1 | c.885C>T p.V295= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV59476836; called by muse, mutect2, varscan2
- SCAF8 | c.1812C>T p.S604= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV63200313; called by muse, mutect2, varscan2
- SCN7A | c.4059C>T p.I1353= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as COSV69274095; called by muse, mutect2, varscan2
- SELE | c.1230C>T p.L410= | Silent (SNP) | VAF 48/155 reads (31%) | catalogued as COSV60977265, COSV60978418; called by muse, mutect2, varscan2
- SIAH3 | c.528G>A p.R176= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV68552798; called by muse, mutect2, varscan2
- SIGLEC5 | c.1062C>T p.S354= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV55782845; called by muse, mutect2
- SLC18A1 | c.468C>T p.F156= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs184315082, COSV52348359; called by muse, mutect2, varscan2
- SLC2A10 | c.22C>T p.L8= | Silent (SNP) | VAF 29/120 reads (24%) | catalogued as COSV63715824; called by muse, mutect2, varscan2
- SLC35G3 | c.780G>A p.G260= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as COSV52010768; called by muse, mutect2, varscan2
- SLC7A9 | c.774C>T p.I258= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs746181158, COSV50091389, COSV99195264; called by muse, mutect2, varscan2
- SLITRK6 | c.450G>A p.V150= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV68391372; called by muse, mutect2, varscan2
- SMR3B | c.177C>T p.I59= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV59229113; called by muse, mutect2, varscan2
- SNX5 | c.1126C>T p.L376= | Silent (SNP) | VAF 43/168 reads (26%) | catalogued as COSV66697593, COSV66698469; called by muse, mutect2, varscan2
- TAS1R1 | c.297G>A p.G99= | Silent (SNP) | VAF 28/195 reads (14%) | catalogued as COSV60229739; called by muse, mutect2, varscan2
- TBC1D21 | c.750C>T p.S250= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs1463821425, COSV55996425; called by muse, mutect2
- TESMIN | c.138C>T p.F46= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV54834658; called by muse, mutect2
- THRAP3 | c.843C>T p.S281= | Silent (SNP) | VAF 27/180 reads (15%) | catalogued as COSV63569453; called by muse, mutect2, varscan2
- THRB | c.174C>T p.L58= | Silent (SNP) | VAF 22/119 reads (18%) | catalogued as COSV62841123; called by muse, mutect2, varscan2
- TMEM42 | c.402C>T p.F134= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV56644580; called by muse, mutect2, varscan2
- TNC | c.3027G>A p.L1009= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV60789291; called by muse, mutect2, varscan2
- TNFAIP1 | c.585C>T p.G195= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV50228825; called by muse, mutect2, varscan2
- TRPC7 | c.78C>T p.I26= | Silent (SNP) | VAF 9/117 reads (8%) | catalogued as COSV61462387; called by muse, mutect2
- TSNARE1 | c.606C>T p.L202= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as rs906256325, COSV56181957; called by muse, mutect2, varscan2
- TTLL11 | c.84C>T p.S28= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV58651733; called by muse, mutect2, varscan2
- TTLL3 | c.768G>A p.R256= | Silent (SNP) | VAF 39/223 reads (17%) | catalogued as COSV59615437; called by muse, mutect2, varscan2
- TTN | c.96243C>A p.T32081= (on ENST00000591111; = p.T24657= on NM_003319.4) | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV60279518; called by muse, mutect2, varscan2
- USH2A | c.14298T>C p.S4766= | Silent (SNP) | VAF 50/148 reads (34%) | catalogued as COSV56362992; called by muse, mutect2, varscan2
- WDR48 | c.39G>A p.R13= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as rs891246457, COSV56531588; called by muse, mutect2, varscan2
- WNK2 | c.4794C>T p.Y1598= (on ENST00000297954 / NM_001282394.1; = p.Y1561= on NM_006648.3) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs1274013250, COSV99942817; called by muse, mutect2, varscan2
- XDH | c.3105G>A p.G1035= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as rs1327388914, COSV101052049, COSV65150781; called by muse, mutect2, varscan2
- ZC3H10 | c.1116A>C p.T372= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV57769744; called by muse, mutect2, varscan2
- ZC3H3 | c.498C>T p.P166= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV52787493; called by muse, mutect2, varscan2
- ZNF319 | c.1221C>T p.G407= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV54623440; called by muse, mutect2, varscan2
- ZNF536 | c.138C>T p.A46= | Silent (SNP) | VAF 25/143 reads (17%) | catalogued as rs1162506647, COSV62823897, COSV62832079; called by muse, mutect2, varscan2
- ZNF568 | c.384C>T p.I128= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV61741188; called by muse, mutect2, varscan2
- ZNF688 | c.672C>T p.F224= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs1158957848, COSV56300016; called by muse, mutect2, varscan2
- ZNRF1 | c.438C>T p.P146= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as COSV57729537; called by muse, mutect2, varscan2
- AC244258.1 | n.546G>A | RNA (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- CDC42BPA | c.2944-3927C>T | Intron (SNP) | VAF 25/87 reads (29%) | catalogued as COSV100505494; called by muse, varscan2
- CLPSL1 | c.-2C>T | 5'UTR (SNP) | VAF 11/86 reads (13%) | catalogued as rs1413015700, COSV100846312; called by muse, mutect2, varscan2
- DCHS2 | n.7274C>T | RNA (SNP) | VAF 9/75 reads (12%) | catalogued as COSV61778097; called by muse, mutect2, varscan2
- DEFB119 | c.61+1334G>A | Intron (SNP) | VAF 25/92 reads (27%) | catalogued as COSV100190753, COSV59267802; called by muse, mutect2, varscan2
- EPPIN | c.92-32G>A | Intron (SNP) | VAF 28/85 reads (33%) | catalogued as rs778558072, COSV100323227; called by muse, mutect2, varscan2
- ERCC6 | c.1397+8320G>T | Intron (SNP) | VAF 23/146 reads (16%) | catalogued as COSV100875951, COSV63394978; called by muse, mutect2, varscan2
- ERCC6 | c.1397+8319T>G | Intron (SNP) | VAF 23/145 reads (16%) | catalogued as COSV100875952; called by muse, mutect2, varscan2
- KCNK1 | c.356-16584C>T | Intron (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- OR2U1P | n.51G>A | RNA (SNP) | VAF 12/104 reads (12%) | catalogued as rs746602718; called by muse, mutect2, varscan2
